Somatic mutation profile of tumor specimen TARGET-20-PAMYGX-09A (aliquot TARGET-20-PAMYGX-09A-02D) from TARGET case TARGET-20-PAMYGX, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.4 years (1,259 days).
Specimen TARGET-20-PAMYGX-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1b39cf72-639b-4fe1-b281-8e4e930320c5.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PAMYGX-14A (Bone Marrow Normal), aliquot TARGET-20-PAMYGX-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0344d919-456b-4707-a1c6-f29c539f7069

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 72/270 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs121918454, CM013417, COSV61005613, COSV61008344, COSV61012146; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- PPP2R2D | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.479); catalogued as COSV70778758, COSV70778965; called by muse, mutect2
